Gene-level copy-number profile of tumor specimen TCGA-AA-3867-01A from TCGA case TCGA-AA-3867, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.0 years (27,028 days).
Specimen TCGA-AA-3867-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.03ffe040-f68e-4507-9f52-65a4a206afb0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3867-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcabe7c3-8dce-4d42-9ea9-2fdb4f5a9415

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 687; copy number 2: 9,423; copy number 3: 23,060; copy number 4: 21,945; copy number 5: 381; copy number 6: 927; copy number 7: 2,483; copy number 8: 909.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3867-01A-01D-1018-01): tumor purity 0.59, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,392 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–47,736,306, 137 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:85,833,377–145,066,685, 933 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7 (broad region; genes not listed).
- chr20:25,919,499–64,313,132, 931 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 687. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
